Somatic mutation profile of cancer-model specimen HCM-BROD-0693-C71-85A (Adherent Cell Line, passage 9; aliquot HCM-BROD-0693-C71-85A-01D-A82H-36), derived from the primary tumor of HCMI case HCM-BROD-0693-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.3 years (24,222 days).
Specimen HCM-BROD-0693-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a62fc053-2227-4f42-9e9a-1da6676a49c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0693-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0693-C71-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb6438f0-573c-402a-9903-82d0f4719234

The open-access MAF lists 77 somatic variants for this specimen: 50 protein-altering or splice-affecting, 27 silent.
By variant classification: Missense Mutation 41, Silent 27, Nonsense Mutation 4, Frame Shift Del 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 354/355 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs786201044, CM004336, COSV100911109, COSV64289087; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 187/187 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 198/431 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs531290635, COSV101239486, COSV67131269; called by muse, mutect2, varscan2
- ARHGAP45 | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 289/846 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as rs374344042; called by muse, mutect2, varscan2
- BMP8A | c.540C>G p.F180L | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV59031999; called by mutect2, varscan2
- CCER1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 277/599 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.8); catalogued as COSV62646987; called by muse, mutect2, varscan2
- CDKN2A | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 353/380 reads (93%) | catalogued as rs138677674, CM994496, COSV58683123; called by muse, mutect2, varscan2
- CETP | c.784C>A p.L262I | Missense Mutation (SNP) | VAF 173/362 reads (48%) | SIFT tolerated (0.82); PolyPhen benign (0.048); catalogued as rs150475423; called by muse, mutect2, varscan2
- CPA4 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 107/427 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs1162447207; called by muse, mutect2, varscan2
- DOCK1 | c.4995C>T p.D1665= | Splice Region (SNP) | VAF 141/311 reads (45%) | catalogued as rs756475538, COSV54739021; called by muse, mutect2, varscan2
- ELAVL3 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 137/501 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs571838282, COSV63646597; called by muse, mutect2, varscan2
- F2RL3 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 339/1064 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs527989109, COSV50186773; called by muse, mutect2, varscan2
- FER | c.1274G>C p.R425P | Missense Mutation (SNP) | VAF 121/227 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55286183; called by muse, mutect2, varscan2
- FLII | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 293/294 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767251437; called by muse, mutect2, varscan2
- GLUD2 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs201021827, COSV60152595; called by muse, mutect2, varscan2
- IGHV1-2 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 194/418 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs561582626; called by muse, mutect2
- IQCN | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 289/856 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs200263958; called by muse, mutect2, varscan2
- KCNK1 | c.750G>A p.T250= | Splice Region (SNP) | VAF 89/299 reads (30%) | catalogued as rs773349901, COSV64036340; called by muse, mutect2, varscan2
- MAST1 | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 187/483 reads (39%) | catalogued as rs377683590; called by muse, mutect2, varscan2
- NCKAP5L | c.3130C>T p.R1044W | Missense Mutation (SNP) | VAF 264/528 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs753774229, COSV60134124; called by muse, mutect2, varscan2
- OR4K13 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 124/273 reads (45%) | catalogued as COSV100237924, COSV59859393; called by muse, mutect2, varscan2
- OR56A1 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 174/388 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs763572368, COSV57362486; called by muse, mutect2
- OR5AS1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 25/492 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100546369; called by muse, mutect2
- RXRG | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 255/374 reads (68%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs746856217, COSV99071763; called by muse, mutect2, varscan2
- SERPINE1 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 182/575 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371179958; called by muse, mutect2, varscan2
- SERPINE3 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 279/415 reads (67%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.543); catalogued as rs376407383; called by muse, mutect2, varscan2
- SH2D3A | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 188/622 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs767313865, COSV55585796; called by muse, mutect2, varscan2
- THSD7B | c.3809G>A p.R1270Q (on ENST00000272643; = p.R1268Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 105/234 reads (45%) | SIFT tolerated (0.93); PolyPhen benign (0.013); catalogued as rs750716218, COSV55711536; called by muse, mutect2, varscan2
- TRPC6 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 247/469 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as rs1485520621; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, varscan2
- CDK19 | c.1198C>A p.Q400K | Missense Mutation (SNP) | VAF 272/632 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COL1A2 | c.2803C>A p.P935T | Missense Mutation (SNP) | VAF 174/643 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- COL5A3 | c.4771_4772del p.K1591Vfs*2 | Frame Shift Del (DEL) | VAF 153/503 reads (30%) | called by mutect2, pindel, varscan2
- DCBLD2 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 129/270 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXJ3 | c.926_929del p.S309Nfs*4 | Frame Shift Del (DEL) | VAF 77/188 reads (41%) | called by mutect2, pindel, varscan2
- FRY | c.5966G>A p.G1989D | Missense Mutation (SNP) | VAF 212/314 reads (68%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FUBP1 | c.132A>T p.K44N | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HOXC12 | c.23A>T p.N8I | Missense Mutation (SNP) | VAF 163/401 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF21B | c.4603G>T p.E1535* (on ENST00000422435 / NM_001252100.2; = p.E1522* on NM_017596.4) | Nonsense Mutation (SNP) | VAF 116/457 reads (25%) | called by muse, mutect2, varscan2
- MYO15A | c.6277C>A p.L2093M | Missense Mutation (SNP) | VAF 154/154 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- NDUFAF7 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 181/371 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PDE2A | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 229/447 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPEF2 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 141/369 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- PTGER1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 288/738 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPRK | c.2916G>A p.M972I (on ENST00000368215 / NM_001291984.2; = p.M973I on NM_002844.4) | Missense Mutation (SNP) | VAF 151/354 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SUGP2 | c.1968_1969del p.A657Sfs*75 | Frame Shift Del (DEL) | VAF 210/862 reads (24%) | called by pindel, varscan2
- TENM4 | c.2782G>T p.V928L | Missense Mutation (SNP) | VAF 139/323 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- TG | c.2033C>A p.A678D | Missense Mutation (SNP) | VAF 48/784 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- VIM | c.13T>G p.S5A | Missense Mutation (SNP) | VAF 416/416 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF569 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 261/528 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADGRB1 | c.198G>A p.S66= | Silent (SNP) | VAF 622/973 reads (64%) | catalogued as rs752538490; called by muse, mutect2, varscan2
- ANO7 | c.1434C>T p.N478= (on ENST00000274979; = p.N424= on NM_001370694.2) | Silent (SNP) | VAF 352/707 reads (50%) | called by muse, mutect2, varscan2
- ANO8 | c.3537C>T p.A1179= | Silent (SNP) | VAF 92/341 reads (27%) | called by mutect2, varscan2
- AP2B1 | c.378C>T p.L126= | Silent (SNP) | VAF 320/502 reads (64%) | catalogued as rs1378297348; called by muse, mutect2, varscan2
- ASPN | c.594C>T p.H198= | Silent (SNP) | VAF 62/138 reads (45%) | catalogued as rs144954352; called by muse, mutect2, varscan2
- BBS2 | c.936G>A p.G312= | Silent (SNP) | VAF 152/312 reads (49%) | called by muse, mutect2, varscan2
- CACNA1F | c.5685C>T p.A1895= | Silent (SNP) | VAF 292/292 reads (100%) | catalogued as rs782554706, COSV100544243; called by muse, mutect2, varscan2
- CACNG5 | c.90C>T p.T30= | Silent (SNP) | VAF 240/850 reads (28%) | catalogued as rs770523089, COSV50055043; called by muse, mutect2
- CD300LB | c.213G>A p.E71= | Silent (SNP) | VAF 236/674 reads (35%) | catalogued as COSV58726509; called by muse, mutect2, varscan2
- CDC42BPG | c.3933C>T p.H1311= | Silent (SNP) | VAF 196/395 reads (50%) | catalogued as rs760868480, COSV61348195; called by muse, mutect2, varscan2
- CXCL14 | c.309C>T p.N103= (on ENST00000337225; = p.N91= on NM_004887.5) | Silent (SNP) | VAF 177/351 reads (50%) | catalogued as COSV61499183, COSV61499269; called by muse, mutect2, varscan2
- DTX1 | c.567G>A p.S189= | Silent (SNP) | VAF 336/747 reads (45%) | catalogued as rs1351094001, COSV99986353; called by muse, mutect2, varscan2
- GRM7 | c.2025G>A p.T675= | Silent (SNP) | VAF 217/417 reads (52%) | catalogued as rs267599934; called by muse, mutect2, varscan2
- MAN1A1 | c.1860C>T p.D620= | Silent (SNP) | VAF 83/202 reads (41%) | catalogued as rs781330587, COSV63788592; called by muse, mutect2, varscan2
- MARCHF2 | c.450G>A p.P150= | Silent (SNP) | VAF 357/1109 reads (32%) | catalogued as rs772382104; called by muse, mutect2, varscan2
- MMD2 | c.516C>T p.A172= | Silent (SNP) | VAF 214/715 reads (30%) | catalogued as rs373175616; called by muse, mutect2, varscan2
- MMP9 | c.2088C>T p.Y696= | Silent (SNP) | VAF 76/458 reads (17%) | catalogued as rs369032528; ClinVar: likely benign; called by muse, varscan2
- MPL | c.372C>G p.V124= | Silent (SNP) | VAF 102/202 reads (50%) | called by muse, mutect2, varscan2
- NCOA1 | c.1188A>T p.P396= | Silent (SNP) | VAF 177/399 reads (44%) | called by muse, mutect2, varscan2
- NFKB2 | c.495C>T p.G165= | Silent (SNP) | VAF 43/220 reads (20%) | called by muse, mutect2, varscan2
- OR2L13 | c.357C>T p.Y119= | Silent (SNP) | VAF 391/612 reads (64%) | catalogued as rs1438157332, COSV63553802; called by muse, mutect2, varscan2
- PTPN23 | c.3655C>T p.L1219= | Silent (SNP) | VAF 275/567 reads (49%) | called by muse, mutect2, varscan2
- RBPMS2 | c.426G>A p.L142= | Silent (SNP) | VAF 176/542 reads (32%) | called by muse, mutect2, varscan2
- SLC22A16 | c.1200C>T p.P400= | Silent (SNP) | VAF 137/274 reads (50%) | catalogued as rs373105261; called by muse, varscan2
- THSD7B | c.786C>T p.S262= | Silent (SNP) | VAF 167/323 reads (52%) | catalogued as rs576768669, COSV55675824, COSV55679461; called by muse, mutect2, varscan2
- USH2A | c.6741C>T p.P2247= | Silent (SNP) | VAF 164/567 reads (29%) | catalogued as rs766287712; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZP2 | c.1641G>A p.A547= | Silent (SNP) | VAF 157/367 reads (43%) | catalogued as rs141607027; called by muse, mutect2, varscan2
